Somatic mutation profile of tumor specimen MP2PRT-PAUKGC-TMP1-A (aliquot MP2PRT-PAUKGC-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,185 days).
Specimen MP2PRT-PAUKGC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66d53cae-ce50-429c-90c6-44b08ef68c13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKGC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKGC-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a6b2d6-54b0-49fc-8e9c-feae535ed665

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TLN2 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967305788, COSV60895942; called by muse, mutect2, varscan2
- ZNF462 | c.6352G>A p.V2118I | Missense Mutation (SNP) | VAF 138/442 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.365); catalogued as rs753969030, COSV52932673; called by muse, mutect2, varscan2
- BRWD3 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NBEA | c.7258T>C p.S2420P | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SP3 | c.416_417dup p.V140Mfs*34 | Frame Shift Ins (INS) | VAF 69/235 reads (29%) | called by mutect2, pindel, varscan2
- CRTAC1 | c.1002C>T p.I334= | Silent (SNP) | VAF 103/244 reads (42%) | catalogued as COSV54001927; called by muse, mutect2, varscan2
